Somatic mutation profile of tumor specimen MBCProject_2622_T1_WES (aliquot MBCProject_2622_T1_WES_1) from CMI case MBCProject_2622, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 56.2 years (20,540 days).
Specimen MBCProject_2622_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6d786f0-87ae-4bfd-b208-2a4981eaaba3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_2622_SALIVA (Saliva), aliquot MBCProject_2622_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9245a8c4-ab71-4dcd-817d-a29c86ddcac5

The open-access MAF lists 22 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Intron 3, Silent 3, Nonsense Mutation 2, Nonstop Mutation 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2264T>C p.L755S | Missense Mutation (SNP) | VAF 25/138 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913470, COSV54062780, COSV54064269; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CDH1 | c.2017C>T p.Q673* | Nonsense Mutation (SNP) | VAF 78/286 reads (27%) | catalogued as COSV55729046; called by muse, mutect2, varscan2
- TYMP | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 54/238 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.075); catalogued as COSV52688599; called by muse, mutect2, varscan2
- UGT2B17 | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1366914945; called by muse, mutect2, varscan2
- C11orf80 | c.1887A>G p.*629Wext*? | Nonstop Mutation (SNP) | VAF 23/131 reads (18%) | called by muse, mutect2, varscan2
- CNTRL | c.1252C>G p.P418A | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CUL1 | c.1144A>T p.M382L | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBXO40 | c.1665G>T p.E555D | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- KLF2 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.87); PolyPhen benign (0.003); called by muse, varscan2
- LRRK1 | c.1010C>G p.S337C | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- LY6D | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 19/159 reads (12%) | called by muse, mutect2, varscan2
- NR2F6 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 9/45 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- PA2G4 | c.1185A>T p.*395Cext*23 | Nonstop Mutation (SNP) | VAF 15/75 reads (20%) | called by muse, mutect2, varscan2
- SPTBN4 | c.1907G>A p.R636Q | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TCF7 | c.286C>G p.P96A | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2
- ZNF699 | c.349A>G p.I117V | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARX | c.819C>G p.A273= | Silent (SNP) | VAF 9/168 reads (5%) | called by muse, mutect2
- PCDHA7 | c.1170G>A p.T390= | Silent (SNP) | VAF 54/246 reads (22%) | catalogued as COSV65346327; called by muse, mutect2, varscan2
- RPS6KA2 | c.1437C>T p.G479= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as rs149149671; called by muse, mutect2, varscan2
- AFF2 | c.1041+56427G>T | Intron (SNP) | VAF 24/105 reads (23%) | called by muse, mutect2, varscan2
- ECT2 | c.2656-1474C>T | Intron (SNP) | VAF 34/191 reads (18%) | catalogued as rs1489491960; called by muse, mutect2, varscan2
- LAMA1 | c.7051-31A>G | Intron (SNP) | VAF 8/204 reads (4%) | called by muse, mutect2
